Gene-level copy-number profile of tumor specimen TCGA-39-5021-01A from TCGA case TCGA-39-5021, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70.9 years (25,895 days).
Specimen TCGA-39-5021-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.74a368da-8c2e-492b-957e-818c0bd1dbd7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-39-5021-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5cfd0331-8b09-45e7-b601-29b1600d801b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 15,529; copy number 2: 27,030; copy number 3: 13,597; copy number 4: 2,494; copy number 5: 10; copy number 6: 391; copy number 7: 15; copy number 9: 746.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-39-5021-01A-01D-1439-01): tumor purity 0.4, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,162 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:84,638,405–90,261,708, 47 genes, copy number 6: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:148,695,994–198,222,513, 896 genes, copy number 6–9 (broad region; genes not listed).
- chr9:5,881,596–6,008,482, 1 gene, copy number 6 (within-gene range 2–6): KIAA2026.
- chr9:6,007,826–6,066,714, 3 genes, copy number 6: MIR4665, RANBP6, AL162384.1.
- chr9:32,540,544–36,677,683, 190 genes, copy number 6 (broad region; genes not listed).
- chr18:78,908,629–79,378,287, 10 genes, copy number 5 (within-gene range 3–5): AC091027.2, AC091027.1, AC091027.3, LINC01896, SALL3, ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3.
- chr22:49,773,283–50,012,659, 15 genes, copy number 7 (within-gene range 3–7): BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL.

Autosomal genes at a single copy (total copy number 1): 13,150. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
